Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A48R, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A48R-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* Addendum *

Patient: [REDACTED]

....

Clinical Diagnosis & History:

Patient h/o retroperitoneal mass previously with path consistent with moderately differentiated leiomyosarcoma.

Specimens Submitted:

- 1: SP: Tumor capsule
- 2: SP: Left common iliac vein
- 3: SP: Left ureter with tumor
- 4: SP: Left colon
- 5: SP: Retroperitoneal tumor

ICD-O-3

leiomyosarcoma, NOS
8890/3

Site: retroperitoneum

9-11-12
RD

C48.0

DIAGNOSIS:

- 1) TUMOR CAPSULE, BIOPSY:
- FRAGMENT OF HIGH GRADE LEIOMYOSARCOMA AND HEMORRHAGE.
- 2) COMMON ILIAC VEIN, LEFT, SEGMENTAL EXCISION:
- VEIN 3.0 CM SEGMENT, ENCASED BY HIGH GRADE LEIOMYOSARCOMA. SOFT TISSUE MARGINS POSITIVE.
- VASCULAR MARGIN NEGATIVE.
- 3) URETER, LEFT, SEGMENTAL RESECTION:
- URETER 1.0 CM SEGMENT, ENCASED AND INVADDED BY HIGH GRADE LEIOMYOSARCOMA.
- SOFT TISSUE MARGIN POSITIVE PERIPHERALLY.
- 4) COLON, LEFT, SEGMENTAL RESECTION:
- SEGMENT OF COLON, 23.0 CM, WITH FOCAL MUCOSAL HYPERPLASTIC CHANGES.
- NO TUMOR IDENTIFIED.
- 5) SOFT TISSUE; RETROPERITONEAL TUMOR, EXCISION:
- HIGH GRADE LEIOMYOSARCOMA, 18.0 CM.
- MARGINS ARE CLOSE BUT NEGATIVE FOR TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

PATH
REPORT

** Continued on next page **

[page 2 of 4]
Special Studies:

Result	Special Stain	Comment
	SMA	
	CD117	
	des	
	CMA (HHF35)	
	IMM RECURT	
	NEG CONT	

Gross Description:

1) The specimen is received in formalin, labeled "Tumor capsule". It consists of an irregularly shaped portion of tan-pink soft tissue, which measures from 0.3 to 0.7 cm in greatest dimension. The specimen is submitted entirely.

Summary of sections:
U - undesignated

2) The specimen is received in formalin, labeled "Left common iliac vein". It consists of a partially tattered segment of vein with attached tumor, which measures 3 cm in length and approximately 1 cm in diameter. The attached tumor measures 4.2 x 1.5 x 1.2 cm. The specimen is serially sectioned revealing tan-white firm cut surfaces. The vascular margins are submitted.

Summary of sections:
VM vascular margin
T - tumor

3) The specimen is received in formalin, labeled "Left ureter with tumor". It consists of a probe patent partially tattered segment of ureter, which measures 1 cm in length and approximately 0.4 cm in diameter. It is encased in tumor. The specimen is submitted entirely.

Summary of sections:
U - undesignated

4) The specimen is received fresh, labeled "Left colon". It consists of a 23 cm segment of large bowel, which measures approximately 5 cm in internal circumference. The mucosa is pink-tan with usual circumferential folds. Two small polyps are identified in the mid portion of the specimen measuring up to 0.5 cm in their greatest dimension. The serosa overlying the pericolic adipose tissue is unremarkable. There is no gross evidence

PATH
REPORT

** Continued on next page **

[page 3 of 4]
----- Page 3 of 4
of tumor.

Summary of sections:
U - undesignated
M - margins

5) The specimen is received fresh, labeled "Retroperitoneal tumor". It consists of a large lobulated soft rubbery mass, which measures 18 x 14 x 9.5 cm. The specimen is inked under sterile conditions and incised revealing lobulated tan fleshy focally yellow necrotic and hemorrhagic cut surfaces. Representative sections are submitted to TPS for research purposes. The specimen weighs 1850 grams.

Summary of sections:
U - undesignated

Summary of Sections:
Part 1: SP: Tumor capsule

Block	Sect.	Site	PCs
1		U	3

Part 2: SP: Left common iliac vein

Block	Sect.	Site	PCs
1		T	2
1		VM	2

Part 3: SP: Left ureter with tumor

Block	Sect.	Site	PCs
2		U	5

Part 4: SP: Left colon

Block	Sect.	Site	PCs
1		M	2
2		U	2

Part 5: SP: Retroperitoneal tumor

Block	Sect.	Site	PCs
10		U	10

Procedures/Addenda:
Addendum

PATH
REPORT

** Continued on next page **

[page 4 of 4]
ADDITIONAL IMMUNOPEROXIDASE STAINS FOR SMA, DESMIN AND CMA ARE POSITIVE, SUPPORTING A DIAGNOSIS OF LEIOMYOSARCOMA. A STAIN FOR C-KIT IS NEGATIVE.

PATH REPORT

** End of Report **

Prior Malignancy / History		

Source: NCI Genomic Data Commons file add8f0ef-daa4-4544-9ff1-bd56cf096927 (TCGA-DX-A48R.365FF7FD-FAF2-4AD2-AE76-596020FC4020.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).